Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TQ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TQ-01A (Primary Tumor).

carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9

Breast, right, simple mastectomy: Infiltrating ductal carcinoma, Nottingham grade III (of III) [tubules 3/3, nuclei 3/3, mitoses 2/3; Nottingham score 8/9], forming a single mass (7.2 x 4.5 x 3.4 cm) located in the upper inner and upper central quadrant of the breast [AJCC pT2]. Angiolymphatic invasion is absent. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. Calcifications are present in malignant ducts. Biopsy site changes are present. All surgical resection margins, including the deep margin, are negative for tumor (minimum tumor free margin, 7.0 cm, deep margin).

Breast, right, supranumerary nipple excision: Intradermal nevus (0.6 cm in greatest dimension).

Lymph nodes, right axillary, dissection: Multiple (2 of 9) right axillary lymph nodes are positive for metastatic carcinoma. The largest lymph node measures 1.4 cm. No extranodal extension identified.

Lymph nodes, highest right axillary, dissection: Multiple (6) highest right axillary lymph nodes are negative for tumor.

Breast, left, simple mastectomy: Nonproliferative fibrocystic changes.

Her-2/NEU has been ordered on paraffin-embedded tissue.

Source: NCI Genomic Data Commons file 6047df3b-c073-4a96-9b1a-10d3e605e48f (TCGA-AR-A0TQ.6061FCA5-A113-4985-905D-E17020F6933E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).